Somatic mutation profile of tumor specimen TCGA-AF-A56N-01A (aliquot TCGA-AF-A56N-01A-12D-A38X-10) from TCGA case TCGA-AF-A56N, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIA; Age at diagnosis: 47.9 years (17,480 days).
Specimen TCGA-AF-A56N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de15e036-030e-437c-87ab-803cea0735ed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AF-A56N-10A (Blood Derived Normal), aliquot TCGA-AF-A56N-10A-01D-A38X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1205f22e-d37e-476d-9d8c-039e57617e04

The open-access MAF lists 168 somatic variants for this specimen: 121 protein-altering or splice-affecting, 42 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 103, Silent 42, Nonsense Mutation 7, Frame Shift Ins 5, Splice Site 3, Frame Shift Del 2, RNA 2, In Frame Ins 1, 5'Flank 1, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 40/91 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.376-1_391del p.X126_splice | Splice Site (DEL) | VAF 22/44 reads (50%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ABCA5 | c.128dup p.L43Ffs*8 | Frame Shift Ins (INS) | VAF 30/88 reads (34%) | catalogued as rs751512043; called by mutect2, varscan2
- ABCB10 | c.1732_1733insG p.I578Sfs*9 | Frame Shift Ins (INS) | VAF 46/205 reads (22%) | catalogued as COSV100747860; called by mutect2, pindel, varscan2
- AP5Z1 | c.1433C>T p.A478V | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs200295277, COSV100804015; called by muse, mutect2, varscan2
- APOH | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 55/146 reads (38%) | catalogued as rs150681833, COSV52771433; called by muse, mutect2, varscan2
- AQP3 | c.224G>A p.G75D | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV53047959; called by muse, varscan2
- BCAT1 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as rs1241125592, COSV99678210; called by muse, mutect2, varscan2
- BRINP1 | c.2159T>C p.F720S | Missense Mutation (SNP) | VAF 73/190 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV56293799; called by muse, mutect2, varscan2
- C12orf50 | c.1219+1G>T p.X407_splice | Splice Site (SNP) | VAF 24/72 reads (33%) | catalogued as COSV53893869, COSV53894465; called by muse, mutect2, varscan2
- CACNA1H | c.4315G>A p.A1439T | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs377604883; called by muse, mutect2, varscan2
- CD300LB | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs778159853, COSV58725057; called by muse, mutect2, varscan2
- CD5L | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.649); catalogued as rs899486061, COSV63821614; called by muse, mutect2, varscan2
- CDH19 | c.1093G>A p.D365N | Missense Mutation (SNP) | VAF 35/54 reads (65%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV50970632; called by muse, mutect2, varscan2
- CERS6 | c.317T>G p.L106R | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99986602; called by muse, mutect2, varscan2
- CHPF | c.2075C>T p.A692V | Missense Mutation (SNP) | VAF 91/224 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as rs767216542, COSV60536203; called by muse, mutect2, varscan2
- CHRD | c.2451+1G>T p.X817_splice | Splice Site (SNP) | VAF 20/48 reads (42%) | catalogued as COSV99200250; called by muse, mutect2, varscan2
- COL6A1 | c.1732G>T p.G578C | Missense Mutation (SNP) | VAF 63/178 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100719980; called by muse, mutect2, varscan2
- CRHR2 | c.454C>T p.H152Y | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100529738; called by muse, mutect2, varscan2
- DKKL1 | c.264G>T p.E88D | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.094); catalogued as COSV99678620; called by muse, mutect2, varscan2
- DLL1 | c.810G>T p.Q270H | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.974); catalogued as COSV100815943; called by muse, mutect2, varscan2
- DTNA | c.1202G>T p.R401M | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.594); catalogued as COSV99311184; called by muse, mutect2
- EGF | c.3466T>A p.S1156T | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.005); catalogued as COSV99490532; called by muse, mutect2, varscan2
- EMD | c.752G>T p.G251V | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as COSV100877344; called by muse, mutect2, varscan2
- ENPP3 | c.311G>C p.G104A | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100716769, COSV62956659; called by muse, mutect2, varscan2
- EPDR1 | c.179G>A p.G60E | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.314); catalogued as rs746506034; called by muse, mutect2
- EPSTI1 | c.517C>A p.L173I | Missense Mutation (SNP) | VAF 45/80 reads (56%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.558); catalogued as COSV100552664; called by muse, mutect2, varscan2
- ERCC6L2 | c.1643G>C p.G548A | Missense Mutation (SNP) | VAF 37/150 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as COSV99998316; called by muse, mutect2, varscan2
- ESPNL | c.1030C>A p.P344T | Missense Mutation (SNP) | VAF 20/474 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.253); catalogued as COSV100547629; called by muse, mutect2
- F13B | c.720C>A p.F240L | Missense Mutation (SNP) | VAF 187/433 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.755); catalogued as COSV100803206; called by muse, mutect2, varscan2
- FAM53B | c.1231G>A p.D411N | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.935); catalogued as COSV100483952; called by muse, mutect2, varscan2
- FAM53B | c.109A>T p.T37S | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99784833; called by muse, mutect2, varscan2
- FAM89A | c.365A>G p.K122R | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.221); catalogued as COSV100792565; called by muse, mutect2
- FCRL3 | c.140T>C p.I47T | Missense Mutation (SNP) | VAF 50/95 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.606); catalogued as rs771551828, COSV100942903; called by muse, mutect2, varscan2
- FIBP | c.595T>A p.F199I | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.094); catalogued as COSV100327219; called by muse, mutect2, varscan2
- FOSB | c.639T>G p.F213L | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1218921120, COSV100798704, COSV100798775; called by muse, mutect2
- FOXP2 | c.1628G>A p.R543H | Missense Mutation (SNP) | VAF 49/160 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1158865993, COSV63495418; called by muse, mutect2, varscan2
- FRMPD3 | c.1561C>T p.R521C | Missense Mutation (SNP) | VAF 76/215 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as COSV99345764; called by muse, mutect2, varscan2
- HLA-DOA | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.861); catalogued as rs200187983, COSV57715079; called by muse, mutect2, varscan2
- HLX | c.938T>C p.L313P | Missense Mutation (SNP) | VAF 15/165 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100854469; called by muse, mutect2
- IBSP | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 105/137 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1316015431, COSV56894879; called by muse, mutect2, varscan2
- IGLV3-27 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs772640582; called by muse, mutect2, varscan2
- KCNH2 | c.2005G>A p.G669S | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.443); catalogued as COSV51128859; called by muse, mutect2, varscan2
- KIF1A | c.3982C>T p.R1328C (on ENST00000320389 / NM_001379639.1; = p.R1320C on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 115/302 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as rs1444137658, COSV100239976; called by muse, mutect2, varscan2
- LCN6 | c.398C>T p.T133I | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.966); catalogued as COSV100366378; called by muse, mutect2, varscan2
- LINGO4 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs771985851, COSV100561762; called by muse, mutect2, varscan2
- LMF1 | c.20C>G p.T7R | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); catalogued as COSV99234675; called by muse, mutect2, varscan2
- LRP1B | c.8262C>A p.S2754R | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.057); catalogued as COSV101253513; called by muse, mutect2, varscan2
- LRRK2 | c.1516C>T p.R506* | Nonsense Mutation (SNP) | VAF 14/106 reads (13%) | catalogued as rs150368439; called by muse, mutect2, varscan2
- MAP1A | c.818A>C p.Q273P | Missense Mutation (SNP) | VAF 65/100 reads (65%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as COSV55806766; called by muse, mutect2, varscan2
- MAP6 | c.2356G>A p.D786N | Missense Mutation (SNP) | VAF 89/173 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV100496489; called by muse, mutect2, varscan2
- MASP2 | c.1721G>A p.G574E | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53569246; called by muse, mutect2, varscan2
- MLLT10 | c.347A>G p.N116S | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as rs1481009950, COSV100307520; called by muse, mutect2, varscan2
- MSH3 | c.177_178insCCCCCAGCG p.A59_A60insPPA | In Frame Ins (INS) | VAF 5/32 reads (16%) | catalogued as rs1412395270; called by pindel, varscan2*
- NALCN | c.1198G>A p.V400M | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as rs781617741, COSV51922612; called by muse, mutect2, varscan2
- NDOR1 | c.772del p.H258Mfs*134 | Frame Shift Del (DEL) | VAF 7/45 reads (16%) | catalogued as COSV61287845; called by mutect2, pindel, varscan2
- NEUROG1 | c.283G>A p.V95I | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.36); catalogued as COSV100130736; called by muse, mutect2, varscan2
- NLRP8 | c.1136T>C p.V379A | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52584394; called by muse, mutect2, varscan2
- OCA2 | c.329C>T p.S110L | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0.003); catalogued as COSV100667023; called by muse, mutect2, varscan2
- OR1B1 | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs754990888, COSV100506417; called by muse, mutect2, varscan2
- OR56A4 | c.134C>G p.S45C | Missense Mutation (SNP) | VAF 62/166 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.02); catalogued as COSV100417473; called by muse, mutect2, varscan2
- OSBPL6 | c.940C>T p.R314* | Nonsense Mutation (SNP) | VAF 39/128 reads (30%) | catalogued as rs1398060667, COSV51920949; called by muse, mutect2, varscan2
- PAPPA2 | c.4876C>T p.R1626C | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as rs751301758, COSV62792263; called by muse, mutect2, varscan2
- PARVB | c.397C>A p.L133M | Missense Mutation (SNP) | VAF 64/179 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.92); catalogued as COSV100114555, COSV58691691; called by muse, mutect2, varscan2
- PAX7 | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.712); catalogued as rs375284574; called by muse, mutect2, varscan2
- PIAS1 | c.1456C>T p.P486S | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV51030498; called by muse, mutect2, varscan2
- PKD1L1 | c.580G>A p.V194I | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99218669; called by muse, mutect2, varscan2
- PLA2G4D | c.1144G>C p.E382Q | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT tolerated (0.17); PolyPhen benign (0.026); catalogued as COSV51819251, COSV99299316; called by muse, mutect2, varscan2
- PLEC | c.5839G>C p.A1947P (on ENST00000322810 / NM_201380.4; = p.A1837P on NM_000445.5) | Missense Mutation (SNP) | VAF 81/234 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV59610249, COSV59622850; called by muse, mutect2, varscan2
- PLXDC2 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 55/119 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.435); catalogued as rs768383816, COSV101022803; called by muse, mutect2, varscan2
- PNLDC1 | c.1426C>T p.R476W | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs764324481, COSV99277182; called by muse, mutect2, varscan2
- PNMA8B | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as COSV66535967; called by muse, mutect2, varscan2
- PRAM1 | c.1412G>A p.R471K | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.99); catalogued as rs886632918, COSV55312383; called by muse, mutect2, varscan2
- PTPN14 | c.2164C>A p.P722T | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT tolerated (0.64); PolyPhen benign (0.014); catalogued as COSV100872382, COSV65286515; called by muse, varscan2
- PUM3 | c.681T>G p.S227R | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.318); catalogued as COSV67395853; called by muse, mutect2, varscan2
- R3HCC1L | c.2078G>A p.R693H (on ENST00000612478 / NM_001256619.2; = p.R679H on NM_014472.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); catalogued as rs772754682, COSV100106977; called by muse, mutect2, varscan2
- RBM12 | c.2401G>A p.G801S | Missense Mutation (SNP) | VAF 347/528 reads (66%) | SIFT tolerated (0.21); PolyPhen benign (0.023); catalogued as rs755229287, COSV100467074, COSV99048073; called by muse, mutect2, varscan2
- RBM5 | c.1333C>T p.P445S | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.221); catalogued as COSV100762170; called by muse, mutect2, varscan2
- RENBP | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as COSV100128511; called by muse, mutect2
- RNASEH2B | c.544A>G p.N182D | Missense Mutation (SNP) | VAF 57/200 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV100352264; called by muse, mutect2, varscan2
- ROBO2 | c.3166A>G p.K1056E | Missense Mutation (SNP) | VAF 103/257 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.164); catalogued as rs751986537, COSV59900505; called by muse, mutect2, varscan2
- RPL3L | c.1137C>G p.F379L | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as COSV99238048; called by muse, mutect2, varscan2
- SCN3A | c.1319A>T p.Q440L | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV99325932; called by muse, mutect2, varscan2
- SCN7A | c.1070T>A p.V357E | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.227); catalogued as COSV69269524; called by muse, mutect2, varscan2
- SEC14L1 | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.826); catalogued as rs1363217168, COSV66720937; called by muse, mutect2, varscan2
- SENP5 | c.1608C>G p.D536E | Missense Mutation (SNP) | VAF 161/426 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as COSV60206367; called by muse, mutect2, varscan2
- SLC22A9 | c.1160G>T p.G387V | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99654766; called by muse, mutect2, varscan2
- SLC35A2 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99504074; called by muse, mutect2
- SLC39A4 | c.1391C>T p.P464L (on ENST00000301305 / NM_001374839.1; = p.P439L on NM_017767.3) | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.098); catalogued as rs1554872599, COSV52777894; called by muse, mutect2, varscan2
- SLC7A5 | c.90G>C p.K30N | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs375232549; called by muse, mutect2, varscan2
- SOX9 | c.1081C>T p.Q361* | Nonsense Mutation (SNP) | VAF 135/281 reads (48%) | catalogued as COSV99818200; called by muse, mutect2, varscan2
- SSX7 | c.420C>A p.C140* | Nonsense Mutation (SNP) | VAF 172/679 reads (25%) | catalogued as COSV99993733; called by muse, mutect2, varscan2
- SYNE2 | c.9541G>T p.E3181* | Nonsense Mutation (SNP) | VAF 178/274 reads (65%) | catalogued as COSV100646868; called by muse, mutect2, varscan2
- TAAR8 | c.468G>T p.W156C | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51585795; called by muse, mutect2, varscan2
- TAF1 | c.4882G>A p.D1628N (on ENST00000373790 / NM_138923.4; = p.D1649N on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/148 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.971); catalogued as COSV52114406, COSV99334708; called by muse, mutect2, varscan2
- TEX11 | c.1115G>A p.G372E (on ENST00000344304; = p.G357E on NM_031276.3) | Missense Mutation (SNP) | VAF 120/415 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as COSV60226557; called by muse, mutect2, varscan2
- THUMPD3 | c.1094C>T p.S365F | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.582); catalogued as COSV100560559; called by muse, mutect2, varscan2
- TMEM132D | c.2193C>A p.F731L | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.84); catalogued as COSV67158945; called by muse, mutect2, varscan2
- TMEM164 | c.735C>A p.D245E (on ENST00000372068 / NM_032227.4; = p.D96E on NM_017698.2) | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99911413; called by muse, mutect2, varscan2
- TMEM175 | c.617T>A p.F206Y | Missense Mutation (SNP) | VAF 33/47 reads (70%) | SIFT deleterious (0.05); PolyPhen benign (0.058); catalogued as COSV99297551; called by muse, mutect2, varscan2
- TMEM74B | c.200A>C p.E67A | Missense Mutation (SNP) | VAF 26/38 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as COSV101121960; called by muse, mutect2, varscan2
- TNFRSF14 | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV100859076; called by muse, mutect2, varscan2
- TP53I13 | c.779G>A p.G260E | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs751635455, COSV99837915; called by muse, mutect2, varscan2
- TRABD | c.1084G>A p.A362T | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs761422252, COSV100326719; called by muse, mutect2, varscan2
- TRIM55 | c.1163C>A p.P388H | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as COSV52544305, COSV99396557; called by muse, mutect2, varscan2
- TTN | c.75714G>C p.Q25238H (on ENST00000591111; = p.Q17814H on NM_003319.4) | Missense Mutation (SNP) | VAF 40/93 reads (43%) | PolyPhen benign (0.001); catalogued as COSV59920241; called by muse, mutect2, varscan2
- UBQLN1 | c.1743A>T p.E581D | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV99973167; called by muse, mutect2, varscan2
- UNC5D | c.2330G>A p.R777H | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as rs1334662855, COSV54772780, COSV54774766; called by muse, mutect2, varscan2
- WFIKKN2 | c.1534G>C p.D512H | Missense Mutation (SNP) | VAF 53/117 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100259742, COSV100260043; called by muse, mutect2, varscan2
- XIRP2 | c.2496A>C p.E832D (on ENST00000628543; = p.E1007D on NM_152381.6) | Missense Mutation (SNP) | VAF 119/326 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54687255; called by muse, mutect2, varscan2
- ZC3H12D | c.706G>T p.G236C | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66323697, COSV66323868; called by muse, mutect2, varscan2
- ZNF671 | c.1543G>T p.E515* | Nonsense Mutation (SNP) | VAF 31/80 reads (39%) | catalogued as COSV58051895; called by muse, mutect2, varscan2
- ZNF689 | c.1454G>C p.S485T | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs777519305, COSV99787871; called by muse, mutect2, varscan2
- ZNF778 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs199891318; called by muse, mutect2, varscan2
- ZNF821 | c.244G>T p.V82F (on ENST00000425432 / NM_001376297.1; = p.V40F on NM_017530.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 57/128 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.025); catalogued as COSV100546721; called by muse, mutect2, varscan2
- ZNF98 | c.305dup p.N102Kfs*12 | Frame Shift Ins (INS) | VAF 66/212 reads (31%) | catalogued as rs757764317; called by mutect2, varscan2
- ABCA12 | c.5012dup p.N1671Kfs*2 (on ENST00000272895 / NM_173076.3; = p.N1353Kfs*2 on NM_015657.3) | Frame Shift Ins (INS) | VAF 48/156 reads (31%) | called by mutect2, varscan2
- APC | c.3847_3851dup p.D1285Lfs*5 | Frame Shift Ins (INS) | VAF 166/258 reads (64%) | called by mutect2, pindel, varscan2
- DCLK2 | c.2293del p.R765Efs*135 | Frame Shift Del (DEL) | VAF 8/72 reads (11%) | called by mutect2, pindel, varscan2
- KANSL1L | c.983C>A p.A328D | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LILRA6 | c.598T>G p.Y200D | Missense Mutation (SNP) | VAF 119/655 reads (18%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ACAD8 | c.807C>T p.A269= | Silent (SNP) | VAF 15/102 reads (15%) | catalogued as rs998953069, COSV55539820, COSV99844453; called by muse, mutect2, varscan2
- AHNAK2 | c.7305G>A p.T2435= | Silent (SNP) | VAF 68/84 reads (81%) | catalogued as rs749939034, COSV60909474; called by muse, mutect2, varscan2
- ANKRD1 | c.639C>T p.S213= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as COSV100865303; called by muse, mutect2, varscan2
- ARHGEF4 | c.1062G>A p.E354= | Silent (SNP) | VAF 68/196 reads (35%) | catalogued as COSV100387676; called by muse, mutect2, varscan2
- ATXN1 | c.1362C>T p.Y454= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as rs775283430, COSV55233615; called by muse, mutect2, varscan2
- BEND3 | c.210C>T p.P70= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs782639825, COSV64680176; called by muse, mutect2, varscan2
- CEP152 | c.4359A>G p.L1453= (on ENST00000380950 / NM_001194998.2; = p.L1397= on NM_014985.4) | Silent (SNP) | VAF 37/59 reads (63%) | catalogued as COSV57857426; called by muse, mutect2, varscan2
- CEP63 | c.1614T>C p.N538= | Silent (SNP) | VAF 32/865 reads (4%) | catalogued as COSV100132598; called by muse, mutect2
- CNKSR2 | c.558C>T p.H186= | Silent (SNP) | VAF 316/684 reads (46%) | catalogued as rs748307605, COSV54261472; called by muse, mutect2, varscan2
- DENND4C | c.3543T>G p.L1181= (on ENST00000434457 / NM_001330640.2; = p.L1132= on NM_017925.7) | Silent (SNP) | VAF 59/137 reads (43%) | catalogued as COSV100727332; called by muse, mutect2, varscan2
- EXOC2 | c.90T>C p.N30= | Silent (SNP) | VAF 28/62 reads (45%) | catalogued as COSV100033002; called by muse, mutect2, varscan2
- FCRL4 | c.264G>A p.R88= | Silent (SNP) | VAF 13/164 reads (8%) | catalogued as COSV99619358; called by muse, mutect2
- FLG | c.10737G>A p.T3579= | Silent (SNP) | VAF 37/100 reads (37%) | catalogued as rs372491432; called by muse, varscan2
- GPR27 | c.1008C>T p.V336= | Silent (SNP) | VAF 35/71 reads (49%) | catalogued as COSV99816152; called by muse, mutect2, varscan2
- HAS1 | c.639C>T p.G213= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as rs370617787, COSV55786912; called by muse, mutect2, varscan2
- HCFC1 | c.5673A>G p.P1891= | Silent (SNP) | VAF 146/560 reads (26%) | catalogued as COSV100128512; called by muse, mutect2, varscan2
- KIAA1522 | c.975G>A p.S325= (on ENST00000373480 / NM_001198972.2; = p.S384= on NM_020888.3) | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as rs538150689, COSV53862919; called by muse, mutect2, varscan2
- MAP7D3 | c.1038G>A p.S346= | Silent (SNP) | VAF 37/154 reads (24%) | catalogued as rs774553997, COSV60170524; called by muse, mutect2, varscan2
- MCTP2 | c.2058C>T p.S686= | Silent (SNP) | VAF 36/129 reads (28%) | catalogued as COSV59151748; called by muse, mutect2, varscan2
- MTERF4 | c.1134C>T p.D378= | Silent (SNP) | VAF 24/77 reads (31%) | catalogued as rs10167328, COSV54089537; called by muse, mutect2
- MUC21 | c.651G>A p.T217= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as rs532108366, COSV66219911; called by muse, mutect2, varscan2
- MYO15A | c.2049G>A p.A683= | Silent (SNP) | VAF 11/20 reads (55%) | catalogued as COSV99231387; called by muse, mutect2, varscan2
- MYO16 | c.3825T>G p.P1275= | Silent (SNP) | VAF 13/83 reads (16%) | catalogued as COSV100696005; called by muse, mutect2, varscan2
- NDUFB8 | c.13A>C p.R5= | Silent (SNP) | VAF 6/73 reads (8%) | catalogued as COSV100144033; called by muse, mutect2
- OR5P3 | c.732C>T p.H244= | Silent (SNP) | VAF 62/179 reads (35%) | catalogued as COSV100103021; called by muse, mutect2, varscan2
- OR7E24 | c.504T>C p.F168= | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as COSV71702140, COSV71702187; called by muse, mutect2, varscan2
- OS9 | c.801G>A p.Q267= | Silent (SNP) | VAF 56/147 reads (38%) | catalogued as COSV99232544; called by muse, mutect2, varscan2
- PARP14 | c.1875A>G p.Q625= | Silent (SNP) | VAF 40/122 reads (33%) | catalogued as rs1395200482, COSV71734222; called by muse, mutect2, varscan2
- PRKAG2 | c.408C>A p.P136= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as COSV55224287, COSV99835772; called by muse, mutect2, varscan2
- PRKAG3 | c.1161C>T p.N387= | Silent (SNP) | VAF 40/119 reads (34%) | catalogued as rs895049770, COSV52102166; called by muse, mutect2, varscan2
- SALL3 | c.2751C>A p.S917= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as COSV101609944; called by muse, mutect2, varscan2
- SLC7A14 | c.1080C>A p.V360= | Silent (SNP) | VAF 44/113 reads (39%) | catalogued as COSV51588587; called by muse, mutect2, varscan2
- SUCLG2 | c.255G>A p.Q85= | Silent (SNP) | VAF 35/93 reads (38%) | catalogued as COSV100213916; called by muse, mutect2, varscan2
- TMEM192 | c.402G>A p.R134= | Silent (SNP) | VAF 69/85 reads (81%) | catalogued as COSV100122004; called by muse, mutect2, varscan2
- TP53TG5 | c.433T>C p.L145= | Silent (SNP) | VAF 23/168 reads (14%) | catalogued as rs948695634, COSV101022312; called by muse, mutect2, varscan2
- TRPA1 | c.1641C>T p.D547= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as rs752559794, COSV100083351; called by muse, mutect2, varscan2
- VCX3A | c.303C>T p.H101= | Silent (SNP) | VAF 44/359 reads (12%) | catalogued as rs773772687, COSV66910730; called by muse, varscan2
- VCX3B | c.303C>T p.H101= | Silent (SNP) | VAF 29/240 reads (12%) | catalogued as rs376239387, COSV66842912; called by muse, mutect2, varscan2
- ZNF517 | c.1017C>T p.H339= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as rs1166093158, COSV63465336; called by muse, mutect2, varscan2
- ZNF536 | c.897C>G p.P299= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV100834786; called by muse, mutect2, varscan2
- ZNF664 | c.582T>A p.T194= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as rs770374028, COSV61877654; called by muse, varscan2
- ZNF664 | c.642G>C p.L214= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs771984577, COSV61877404; called by muse, varscan2
- AC024598.1 | c.1130-1520A>C | Intron (SNP) | VAF 31/96 reads (32%) | catalogued as COSV60825077; called by muse, mutect2, varscan2
- DCAF13 | chr8:103415344 T>G | 5'Flank (SNP) | VAF 51/155 reads (33%) | catalogued as COSV52567093, COSV52567749, COSV52568626; called by muse, mutect2, varscan2
- IGLL3P | n.343C>A | RNA (SNP) | VAF 17/102 reads (17%) | catalogued as rs111482791; called by muse, mutect2, varscan2
- SSPOP | n.14033C>T | RNA (SNP) | VAF 28/81 reads (35%) | catalogued as rs1391212310, COSV100947056; called by muse, mutect2, varscan2
- TBX1 | chr22:19782982 A>C | 3'Flank (SNP) | VAF 5/67 reads (7%) | catalogued as COSV100283960; called by muse, mutect2
